Gene-level copy-number profile of tumor specimen TCGA-49-4501-01A from TCGA case TCGA-49-4501, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.9 years (24,817 days).
Specimen TCGA-49-4501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.97fa959e-4845-4082-844a-2c1ce98cba1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4501-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d1d3122-1d4c-48c6-8e81-e37f36a70de1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,367; copy number 2: 20,272; copy number 3: 24,065; copy number 4: 10,824; copy number 5: 596; copy number 6: 1,405; copy number 7: 71; copy number 8: 23; copy number 9: 27; copy number 11: 37; copy number 12: 54; copy number 14: 26; copy number 20: 38; copy number 24: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4501-01A-01D-1204-01): tumor purity 0.43, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 285 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,140,391–121,580,524, 71 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:146,288,596–147,295,765, 27 genes, copy number 9: RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, AC245407.2, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L.
- chr1:149,903,318–150,513,789, 23 genes, copy number 8: SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1.
- chr12:32,790,755–40,570,832, 61 genes, copy number 11–20 (within-gene range 2–20) (broad region; genes not listed).
- chr12:40,728,811–40,729,897, 1 gene, copy number 12: AC016144.1.
- chr12:65,050,626–66,066,338, 22 genes, copy number 12 (within-gene range 2–12): WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:67,571,197–71,441,898, 80 genes, copy number 11–24 (within-gene range 2–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,367. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
